Somatic mutation profile of tumor specimen MP2PRT-PATCKZ-TMP1-A (aliquot MP2PRT-PATCKZ-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATCKZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,380 days).
Specimen MP2PRT-PATCKZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fdd0405-9725-4858-b9fc-f86ea4b16319.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCKZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCKZ-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ad372f8-7fcb-4cb7-bfc4-cd8a90c7665d

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs764506198, COSV57058398; called by muse, mutect2, varscan2
- BNC1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.061); catalogued as rs951635729; called by muse, mutect2, varscan2
- CFAP43 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 62/477 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538157333; called by muse, mutect2, varscan2
- CHRNA7 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 110/685 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1566895467; called by muse, mutect2, varscan2
- CTCF | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 120/434 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1243010179, COSV50486171; called by muse, mutect2, varscan2
- ENO4 | c.1633C>T p.R545W (on ENST00000622726; = p.R542W on NM_001242699.2) | Missense Mutation (SNP) | VAF 34/576 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs753741582, COSV99599314; called by muse, mutect2
- FAT3 | c.9292G>A p.V3098M | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs775214608; called by muse, mutect2
- GPR31 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as rs369377204; called by muse, mutect2, varscan2
- HIGD1A | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1215075284; called by muse, mutect2, varscan2
- HSPA1L | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 50/802 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs767137456; called by muse, mutect2
- KRTAP11-1 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); catalogued as rs199724044, COSV60095174; called by muse, varscan2
- MYO10 | c.5326G>A p.E1776K | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs766063678; called by muse, mutect2, varscan2
- PTPRH | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 198/600 reads (33%) | catalogued as COSV54747896; called by muse, mutect2, varscan2
- SDR9C7 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs754632093, COSV53289996; called by muse, mutect2, varscan2
- SOX5 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 124/363 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755080290; called by muse, mutect2, varscan2
- A3GALT2 | c.916G>C p.V306L | Missense Mutation (SNP) | VAF 217/609 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DES | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 122/558 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, varscan2
- FLT3 | c.1714T>A p.Y572N | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, varscan2
- OR6B2 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 29/600 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- RYR3 | c.10594G>A p.A3532T (on ENST00000389232; = p.A3533T on NM_001036.6) | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TCF4 | c.576_577insCCTCC p.D193Pfs*43 | Frame Shift Ins (INS) | VAF 43/295 reads (15%) | called by mutect2, varscan2
- UBE2O | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 113/453 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- D2HGDH | c.879G>A p.L293= | Silent (SNP) | VAF 96/417 reads (23%) | catalogued as COSV100345119; called by muse, mutect2, varscan2
- DLG3 | c.123A>G p.P41= | Silent (SNP) | VAF 76/936 reads (8%) | catalogued as COSV52087327; called by muse, mutect2
- DNAH12 | c.729A>G p.S243= | Silent (SNP) | VAF 23/255 reads (9%) | catalogued as rs762470082; called by muse, mutect2
- KNDC1 | c.1926C>T p.S642= | Silent (SNP) | VAF 155/687 reads (23%) | catalogued as rs773810392, COSV58832385; called by muse, mutect2, varscan2
- PPP1R26 | c.3189C>T p.S1063= | Silent (SNP) | VAF 166/485 reads (34%) | catalogued as rs779905125; called by muse, mutect2, varscan2
- RYR2 | c.12540C>T p.G4180= | Silent (SNP) | VAF 99/367 reads (27%) | catalogued as rs772125105, COSV63694292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.3300C>T p.T1100= | Silent (SNP) | VAF 89/378 reads (24%) | catalogued as rs200804723, COSV99325523; called by muse, mutect2, varscan2
- SKOR2 | c.285G>A p.T95= | Silent (SNP) | VAF 28/670 reads (4%) | catalogued as COSV68550059; called by muse, mutect2
- TMEM181 | c.78G>A p.A26= | Silent (SNP) | VAF 146/619 reads (24%) | called by muse, mutect2, varscan2
- YY1AP1 | c.1449T>G p.T483= (on ENST00000295566 / NM_139118.2; = p.T426= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/348 reads (25%) | called by muse, mutect2, varscan2
- ADCY1 | c.*7831C>T | 3'UTR (SNP) | VAF 10/326 reads (3%) | catalogued as rs896765862; called by muse, mutect2
